Somatic mutation profile of tumor specimen TCGA-CN-6021-01A (aliquot TCGA-CN-6021-01A-11D-1683-08) from TCGA case TCGA-CN-6021, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; Tumor grade: G2; Age at diagnosis: 63.6 years (23,212 days).
Specimen TCGA-CN-6021-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 498b1082-ba48-4341-8fbe-621cca3f6512.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CN-6021-10A (Blood Derived Normal), aliquot TCGA-CN-6021-10A-01D-1683-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6da09c06-7e1d-4a0b-bfd8-4f3687189879

The open-access MAF lists 321 somatic variants for this specimen: 247 protein-altering or splice-affecting, 66 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 209, Silent 66, Nonsense Mutation 17, Frame Shift Del 12, Intron 4, Frame Shift Ins 3, Splice Site 3, RNA 2, Translation Start Site 1, In Frame Del 1, 3'Flank 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.221A>T p.D74V | Missense Mutation (SNP) | VAF 7/15 reads (47%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM165602, COSV58684939, COSV58689077; called by muse, mutect2, varscan2
- NOTCH1 | c.1070_1072del p.F357del | In Frame Del (DEL) | VAF 14/28 reads (50%) | hotspot (GDC flag); called by mutect2, varscan2
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 32/65 reads (49%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.5594C>G p.S1865C | Missense Mutation (SNP) | VAF 31/57 reads (54%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.946); catalogued as COSV101330051; called by muse, mutect2, varscan2
- ACAD11 | c.28G>T p.D10Y | Missense Mutation (SNP) | VAF 15/144 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV99392081; called by muse, mutect2, varscan2
- ACER1 | c.773G>A p.R258Q | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs144461069, COSV100034169; called by muse, mutect2, varscan2
- ADAM28 | c.325G>T p.G109* | Nonsense Mutation (SNP) | VAF 9/42 reads (21%) | catalogued as COSV56105720; called by muse, mutect2, varscan2
- ADGRB3 | c.1662T>A p.H554Q | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs1562107180, COSV101000814; called by muse, mutect2, varscan2
- ADGRB3 | c.3186del p.G1063Vfs*3 | Frame Shift Del (DEL) | VAF 14/43 reads (33%) | catalogued as COSV53239423; called by mutect2, pindel, varscan2
- ADGRG4 | c.7462G>C p.E2488Q | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.644); catalogued as COSV99795588; called by muse, mutect2, varscan2
- AFDN | c.3375G>C p.K1125N | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.345); catalogued as COSV100653023; called by muse, mutect2, varscan2
- AGBL2 | c.1211A>T p.Q404L | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.253); catalogued as COSV100101713; called by muse, mutect2, varscan2
- ALKBH3 | c.769-1G>A p.X257_splice | Splice Site (SNP) | VAF 14/93 reads (15%) | catalogued as COSV57023287; called by muse, mutect2, varscan2
- AMER1 | c.1016G>T p.S339I | Missense Mutation (SNP) | VAF 91/221 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); catalogued as COSV100366178; called by muse, mutect2, varscan2
- AMIGO3 | c.1000G>A p.D334N | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs777353932, COSV57537600; called by muse, mutect2, varscan2
- ANKRD6 | c.1832G>T p.G611V (on ENST00000339746 / NM_001242809.2; = p.G606V on NM_014942.4) | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.051); catalogued as COSV100329936; called by muse, mutect2, varscan2
- ANKS1B | c.1759G>A p.D587N | Missense Mutation (SNP) | VAF 43/162 reads (27%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs866244804, COSV100245739, COSV61365156; called by muse, mutect2, varscan2
- ARHGAP1 | c.967C>T p.R323W | Missense Mutation (SNP) | VAF 16/105 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs544447260, COSV100357934; called by muse, mutect2, varscan2
- ARHGAP12 | c.652G>T p.E218* | Nonsense Mutation (SNP) | VAF 17/81 reads (21%) | catalogued as COSV100260613; called by muse, mutect2, varscan2
- ARHGAP33 | c.3048G>T p.R1016S | Missense Mutation (SNP) | VAF 42/95 reads (44%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.169); catalogued as COSV99137384; called by muse, mutect2, varscan2
- ARMCX2 | c.1519G>C p.V507L | Missense Mutation (SNP) | VAF 14/222 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.515); catalogued as COSV100168168; called by muse, mutect2
- ARSI | c.1259G>A p.R420H | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs147847092; called by muse, mutect2, varscan2
- ASZ1 | c.664G>T p.A222S | Missense Mutation (SNP) | VAF 32/111 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99498036; called by muse, mutect2, varscan2
- ATP13A4 | c.2674del p.E892Kfs*21 | Frame Shift Del (DEL) | VAF 23/127 reads (18%) | catalogued as COSV61319647; called by mutect2, pindel, varscan2
- ATP2B3 | c.1289C>A p.P430Q | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54852475; called by muse, mutect2, varscan2
- ATP7B | c.349G>A p.G117R | Missense Mutation (SNP) | VAF 34/88 reads (39%) | SIFT tolerated (0.33); PolyPhen benign (0.158); catalogued as COSV99666480; called by muse, mutect2, varscan2
- ATP8B2 | c.2979G>C p.Q993H (on ENST00000672630; = p.Q960H on NM_001367934.1 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV100528002; called by muse, mutect2, varscan2
- BBS9 | c.436G>T p.V146L | Missense Mutation (SNP) | VAF 30/87 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.129); catalogued as COSV99628325; called by muse, mutect2, varscan2
- BEND2 | c.949G>A p.E317K | Missense Mutation (SNP) | VAF 32/125 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.078); catalogued as COSV101192030; called by muse, mutect2, varscan2
- BICD1 | c.818C>T p.A273V | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0.061); catalogued as rs1351328727, COSV99862438; called by muse, mutect2
- BIRC6 | c.667C>T p.L223F | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.9); catalogued as COSV101428325; called by muse, mutect2, varscan2
- BIRC6 | c.9124A>G p.T3042A | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.142); catalogued as COSV101428326; called by muse, mutect2, varscan2
- BRINP1 | c.461C>A p.S154* | Nonsense Mutation (SNP) | VAF 41/61 reads (67%) | catalogued as COSV99775536; called by muse, mutect2, varscan2
- BRWD3 | c.3425C>T p.S1142F | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as rs1312187164, COSV100956097; called by muse, mutect2, varscan2
- BTG1 | c.365G>T p.C122F | Missense Mutation (SNP) | VAF 27/104 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55458097; called by muse, mutect2, varscan2
- C11orf87 | c.486T>G p.C162W | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.259); catalogued as COSV100535804; called by muse, mutect2, varscan2
- C3 | c.3265G>C p.A1089P | Missense Mutation (SNP) | VAF 29/228 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55568519, COSV55569986; called by muse, mutect2, varscan2
- CACNA2D1 | c.745G>T p.A249S | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.061); catalogued as COSV100665302, COSV100666693; called by muse, mutect2, varscan2
- CACNG6 | c.623C>A p.P208H (on ENST00000252729 / NM_145814.1; = p.P137H on NM_031897.2) | Missense Mutation (SNP) | VAF 43/95 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.754); catalogued as COSV99403455; called by muse, mutect2, varscan2
- CATSPERD | c.2320G>T p.A774S | Missense Mutation (SNP) | VAF 95/170 reads (56%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.053); catalogued as COSV100486796; called by muse, mutect2, varscan2
- CBLN2 | c.347A>T p.Y116F | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV99504407; called by muse, mutect2, varscan2
- CCDC178 | c.2470G>T p.A824S (on ENST00000383096 / NM_001105528.3; = p.A786S on NM_198995.3) | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.938); catalogued as COSV100285008; called by muse, mutect2, varscan2
- CCL25 | c.411G>C p.K137N | Missense Mutation (SNP) | VAF 49/108 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV99495166; called by muse, mutect2, varscan2
- CD226 | c.949A>T p.T317S | Missense Mutation (SNP) | VAF 36/104 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.027); catalogued as COSV99711143; called by muse, mutect2, varscan2
- CDH19 | c.205G>C p.D69H | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as COSV100051626; called by muse, mutect2, varscan2
- CDH7 | c.1022T>C p.I341T | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.783); catalogued as rs1568215340, COSV100542437; called by muse, mutect2, varscan2
- CENPE | c.6197T>A p.I2066K | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV99478012; called by muse, varscan2
- CENPE | c.2927A>T p.H976L | Missense Mutation (SNP) | VAF 8/11 reads (73%) | SIFT deleterious (0.03); PolyPhen benign (0.058); catalogued as COSV99478015; called by muse, mutect2, varscan2
- CFAP206 | c.455C>G p.T152S | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as COSV99739589, COSV99739713; called by muse, mutect2, varscan2
- CFHR4 | c.1160C>T p.A387V (on ENST00000367416 / NM_001201551.2; = p.A141V on NM_006684.5) | Missense Mutation (SNP) | VAF 40/155 reads (26%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.546); catalogued as COSV99260515; called by muse, mutect2, varscan2
- CHAF1B | c.1178G>T p.R393I | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0.022); catalogued as COSV100023568; called by muse, mutect2, varscan2
- CHAT | c.592T>G p.W198G | Missense Mutation (SNP) | VAF 49/145 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100340194; called by muse, mutect2, varscan2
- CHCHD4 | c.236C>T p.T79M (on ENST00000396914 / NM_001098502.2; = p.T92M on NM_144636.3) | Missense Mutation (SNP) | VAF 22/42 reads (52%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.708); catalogued as rs758658272, COSV99853876; called by muse, mutect2, varscan2
- CHD1 | c.4701A>T p.K1567N | Missense Mutation (SNP) | VAF 65/144 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0.202); catalogued as COSV99399475; called by muse, mutect2, varscan2
- CHST2 | c.1202G>A p.S401N | Missense Mutation (SNP) | VAF 24/169 reads (14%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.708); catalogued as COSV100535971, COSV58887423; called by muse, mutect2, varscan2
- CNOT1 | c.1957G>T p.A653S | Missense Mutation (SNP) | VAF 26/95 reads (27%) | SIFT tolerated (0.76); PolyPhen benign (0.015); catalogued as rs780462497, COSV100409344; called by muse, mutect2, varscan2
- CNTN4 | c.2097del p.E700Kfs*19 | Frame Shift Del (DEL) | VAF 11/40 reads (28%) | catalogued as COSV61879584; called by mutect2, pindel, varscan2
- CNTN6 | c.1741A>G p.T581A | Missense Mutation (SNP) | VAF 34/86 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100610765; called by muse, mutect2, varscan2
- COL1A2 | c.2237C>A p.P746H | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.533); catalogued as COSV99799832; called by muse, mutect2
- COL3A1 | c.2140G>T p.G714W | Missense Mutation (SNP) | VAF 108/162 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM1412582, COSV100483074; called by muse, mutect2, varscan2
- COL6A5 | c.7559C>A p.T2520K (on ENST00000312481; = p.T2516K on NM_153264.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.052); catalogued as COSV99593269; called by muse, mutect2
- CPPED1 | c.584G>A p.R195Q | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT tolerated (0.83); PolyPhen benign (0.015); catalogued as rs199709074; called by muse, mutect2, varscan2
- CRB1 | c.1978T>A p.S660T | Missense Mutation (SNP) | VAF 38/110 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.341); catalogued as COSV100957892; called by muse, mutect2, varscan2
- CSMD3 | c.7955C>A p.T2652K (on ENST00000297405 / NM_001363185.1; = p.T2548K on NM_052900.3) | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52186438, COSV52276704, COSV99835151; called by muse, mutect2, varscan2
- CTNND2 | c.1519C>T p.Q507* | Nonsense Mutation (SNP) | VAF 26/124 reads (21%) | catalogued as COSV100476968; called by muse, mutect2, varscan2
- CYP2C9 | c.445G>A p.A149T | Missense Mutation (SNP) | VAF 40/87 reads (46%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.874); catalogued as rs754487195, CM1412019, COSV99582741, COSV99583152; called by muse, mutect2, varscan2
- DACH2 | c.415C>G p.P139A | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV100913290; called by muse, mutect2, varscan2
- DACH2 | c.1225C>A p.H409N | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.36); PolyPhen benign (0.01); catalogued as COSV100913292; called by muse, mutect2
- DACH2 | c.1344T>G p.F448L | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.084); catalogued as COSV100913296; called by muse, mutect2, varscan2
- DCAF4L2 | c.118G>T p.A40S | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV100150917, COSV60481430; called by muse, mutect2, varscan2
- DDX1 | c.1157G>A p.R386K | Missense Mutation (SNP) | VAF 42/171 reads (25%) | SIFT tolerated (0.58); PolyPhen benign (0.129); catalogued as COSV99246314; called by muse, mutect2, varscan2
- DIAPH2 | c.2022G>T p.L674F | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100232991; called by muse, mutect2, varscan2
- DIP2A | c.4228C>T p.H1410Y | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.625); catalogued as COSV59471947; called by muse, mutect2
- DKC1 | c.362G>T p.S121I | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV101059883; called by muse, mutect2, varscan2
- DMBT1 | c.601T>A p.C201S | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100353054; called by muse, mutect2, varscan2
- DMD | c.10612C>A p.P3538T | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV100627356; called by muse, mutect2, varscan2
- DMXL1 | c.4844C>T p.T1615I | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV100224007; called by muse, mutect2, varscan2
- DNAH5 | c.12216T>A p.Y4072* | Nonsense Mutation (SNP) | VAF 26/93 reads (28%) | catalogued as COSV99450136; called by muse, mutect2, varscan2
- DOCK11 | c.4841C>G p.T1614S | Missense Mutation (SNP) | VAF 35/121 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as COSV52234031, COSV99353889; called by muse, mutect2, varscan2
- DPPA4 | c.373G>T p.A125S | Missense Mutation (SNP) | VAF 18/157 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV100169445; called by muse, mutect2, varscan2
- DRP2 | c.29C>T p.P10L | Missense Mutation (SNP) | VAF 52/190 reads (27%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as rs909100703, COSV100871919, COSV65810317; called by muse, mutect2, varscan2
- EEF1AKNMT | c.1145G>T p.G382V (on ENST00000361735 / NM_015935.5; = p.G296V on NM_014955.3) | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100675875; called by muse, mutect2, varscan2
- ELMO1 | c.1579G>A p.D527N | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.194); catalogued as rs1258087833, COSV100164626, COSV100164812; called by muse, mutect2, varscan2
- ERO1A | c.1346G>C p.R449T | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101193632; called by muse, mutect2, varscan2
- ETNPPL | c.191C>A p.P64Q | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV99625268; called by muse, mutect2, varscan2
- EXOC3 | c.2168G>A p.S723N | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV100155346; called by muse, mutect2
- EYA2 | c.206A>T p.Y69F | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as COSV100426874; called by muse, mutect2, varscan2
- EYA4 | c.1843C>A p.Q615K (on ENST00000531901 / NM_001301013.1; = p.Q609K on NM_004100.5) | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT tolerated (0.29); PolyPhen benign (0.023); catalogued as rs1475111574, COSV100765903; called by muse, mutect2, varscan2
- FAM83C | c.1978G>A p.A660T | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); catalogued as rs1336137300, COSV100981579; called by muse, mutect2, varscan2
- FANCD2 | c.748T>A p.S250T | Missense Mutation (SNP) | VAF 36/76 reads (47%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.998); catalogued as COSV99811356; called by muse, varscan2
- FBN1 | c.1352A>T p.D451V | Missense Mutation (SNP) | VAF 12/103 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100355170; called by muse, mutect2, varscan2
- FGF6 | c.191G>T p.G64V | Missense Mutation (SNP) | VAF 26/120 reads (22%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.589); catalogued as COSV99960256; called by muse, mutect2, varscan2
- FHL1 | c.731C>A p.A244D | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (0.38); PolyPhen benign (0.024); catalogued as COSV100600793; called by muse, mutect2, varscan2
- FN1 | c.6529G>A p.D2177N (on ENST00000359671 / NM_001365524.2; = p.D2146N on NM_002026.4) | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (0.54); PolyPhen benign (0.007); catalogued as COSV100117196; called by muse, mutect2, varscan2
- FNBP1 | c.1764G>A p.W588* | Nonsense Mutation (SNP) | VAF 30/63 reads (48%) | catalogued as COSV100852707; called by muse, mutect2, varscan2
- FOXA1 | c.521C>T p.S174L | Missense Mutation (SNP) | VAF 29/209 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99163462; called by muse, mutect2, varscan2
- FOXN2 | c.707C>A p.S236Y | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV100489230; called by muse, mutect2, varscan2
- FSCB | c.634A>T p.N212Y | Missense Mutation (SNP) | VAF 37/143 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.025); catalogued as COSV61217461; called by muse, mutect2, varscan2
- FUT8 | c.1532A>C p.Y511S (on ENST00000360689 / NM_001371534.1; = p.Y348S on NM_004480.4) | Missense Mutation (SNP) | VAF 41/125 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.127); catalogued as COSV100651379; called by muse, mutect2, varscan2
- GEMIN2 | c.608G>A p.G203E | Missense Mutation (SNP) | VAF 26/167 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99158244; called by muse, mutect2, varscan2
- GLB1L3 | c.931G>A p.G311R | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs751380469, COSV66280945; called by muse, mutect2, varscan2
- GLI2 | c.1004A>G p.N335S | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT tolerated (0.61); PolyPhen benign (0.006); catalogued as COSV100083284; called by muse, mutect2, varscan2
- GOLGA8G | c.1407G>A p.M469I | Missense Mutation (SNP) | VAF 12/103 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.043); catalogued as COSV100284642; called by muse, mutect2, varscan2
- GOLIM4 | c.1721del p.P574Qfs*24 | Frame Shift Del (DEL) | VAF 94/224 reads (42%) | catalogued as COSV58329921; called by mutect2, pindel, varscan2
- GPR119 | c.820C>G p.L274V | Missense Mutation (SNP) | VAF 34/106 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.083); catalogued as COSV99358634; called by muse, mutect2, varscan2
- GPR12 | c.478A>T p.M160L | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated (0.47); PolyPhen benign (0.015); catalogued as COSV101197977; called by muse, mutect2, varscan2
- GPR143 | c.1040C>A p.P347H | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.755); catalogued as COSV101102241; called by muse, mutect2, varscan2
- GPR63 | c.887T>A p.L296Q | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV100013366; called by muse, mutect2, varscan2
- HCCS | c.695G>T p.G232V | Missense Mutation (SNP) | VAF 31/126 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100335690; called by muse, mutect2, varscan2
- HDAC9 | c.1152G>C p.E384D | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.809); catalogued as COSV101286777, COSV67773804; called by muse, mutect2, varscan2
- HK2 | c.1313G>T p.C438F | Missense Mutation (SNP) | VAF 89/366 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV99309076; called by muse, mutect2, varscan2
- IGKJ2 | c.14G>A p.G5D | Missense Mutation (SNP) | VAF 17/53 reads (32%) | catalogued as rs762374028; called by muse, mutect2, varscan2
- IGKV3-15 | c.218C>A p.T73N | Missense Mutation (SNP) | VAF 31/148 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs764846790; called by muse, mutect2, varscan2
- IL17F | c.316G>T p.G106C | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100277216; called by muse, mutect2, varscan2
- IMPG1 | c.1343C>T p.P448L | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs375185954; called by muse, mutect2, varscan2
- ISY1-RAB43 | c.781A>G p.M261V | Missense Mutation (SNP) | VAF 28/144 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.219); catalogued as rs749056720, COSV99860806; called by muse, mutect2, varscan2
- ITGB5 | c.1034A>G p.Y345C | Missense Mutation (SNP) | VAF 24/125 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99950727; called by muse, mutect2, varscan2
- ITPRID2 | c.3144G>T p.M1048I | Missense Mutation (SNP) | VAF 60/178 reads (34%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as rs1484859300, COSV100238312; called by muse, mutect2, varscan2
- KBTBD3 | c.1060T>A p.C354S | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); catalogued as COSV101595691; called by muse, mutect2, varscan2
- KCNH4 | c.179T>C p.V60A | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99237251; called by muse, mutect2, varscan2
- KCNMB3 | c.47G>T p.R16L | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.345); catalogued as COSV100566716, COSV62895383; called by muse, mutect2, varscan2
- KCNT2 | c.1970C>G p.P657R | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.067); catalogued as COSV99653914; called by muse, mutect2
- KCNV1 | c.1011G>T p.M337I | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as COSV99819120; called by muse, mutect2, varscan2
- KIAA1109 | c.457G>T p.G153C | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99164080; called by muse, mutect2, varscan2
- KLHL13 | c.211A>G p.S71G | Missense Mutation (SNP) | VAF 27/96 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.088); catalogued as COSV99451694; called by muse, mutect2, varscan2
- KLHL34 | c.1199C>A p.P400Q | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV101069927; called by muse, mutect2, varscan2
- KLHL34 | c.721G>T p.G241C | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.071); catalogued as COSV101069929; called by muse, mutect2, varscan2
- KMT2A | c.1589G>A p.R530K | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.036); catalogued as COSV100628922; called by muse, mutect2
- KRBA1 | c.1648G>A p.E550K | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.125); catalogued as rs763076723, COSV99752120; called by muse, mutect2, varscan2
- KRT24 | c.1004G>C p.R335P | Missense Mutation (SNP) | VAF 49/167 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.116); catalogued as COSV99232032; called by muse, mutect2, varscan2
- MAGEB3 | c.224T>C p.V75A | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV100854701; called by muse, mutect2, varscan2
- MAGEE1 | c.479C>T p.P160L | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0); catalogued as rs782292584, COSV100819400; called by muse, mutect2, varscan2
- MECOM | c.94G>T p.A32S | Missense Mutation (SNP) | VAF 5/75 reads (7%) | SIFT tolerated, low confidence (0.73); PolyPhen benign (0.025); catalogued as COSV101527924; called by muse, mutect2
- MED1 | c.3971C>A p.P1324Q | Missense Mutation (SNP) | VAF 38/127 reads (30%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as COSV100327851; called by muse, mutect2, varscan2
- MED12L | c.3064C>T p.H1022Y | Missense Mutation (SNP) | VAF 83/214 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.188); catalogued as rs752982478, COSV99853256; called by muse, mutect2, varscan2
- MEFV | c.2053G>T p.E685* | Nonsense Mutation (SNP) | VAF 54/178 reads (30%) | catalogued as CM156827, COSV99560904; called by muse, mutect2, varscan2
- MID2 | c.1827C>A p.Y609* | Nonsense Mutation (SNP) | VAF 24/105 reads (23%) | catalogued as COSV53315235, COSV99464759; called by muse, mutect2, varscan2
- MTMR7 | c.1546T>A p.S516T | Missense Mutation (SNP) | VAF 45/146 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.17); catalogued as COSV99472449; called by muse, mutect2, varscan2
- MXRA5 | c.6527C>A p.P2176Q | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV54255614, COSV99477081; called by muse, mutect2, varscan2
- MYH6 | c.4911G>A p.M1637I | Missense Mutation (SNP) | VAF 13/111 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV100676622; called by muse, mutect2
- MYOCD | c.177G>A p.K59= | Splice Region (SNP) | VAF 13/66 reads (20%) | catalogued as COSV100590809; called by muse, mutect2, varscan2
- NARS1 | c.839G>A p.G280D | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV99900599; called by muse, mutect2, varscan2
- NAV3 | c.2348C>T p.T783M | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.828); catalogued as rs745934944, COSV99891334; called by muse, mutect2, varscan2
- NDP | c.49G>A p.V17M | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.046); catalogued as CD116240, COSV100955775; called by muse, mutect2, varscan2
- NKAP | c.82C>A p.P28T | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as rs1335827840, COSV101004229; called by muse, mutect2, varscan2
- NPR2 | c.865G>T p.A289S | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.022); catalogued as COSV100709481; called by muse, mutect2
- NRIP3 | c.233G>T p.S78I | Missense Mutation (SNP) | VAF 43/99 reads (43%) | SIFT tolerated (0.21); PolyPhen benign (0.006); catalogued as COSV100487182; called by muse, mutect2, varscan2
- NYNRIN | c.3605C>G p.P1202R | Missense Mutation (SNP) | VAF 39/212 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as COSV101230603; called by muse, mutect2, varscan2
- OGDH | c.1351G>T p.D451Y | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99758463, COSV99758932; called by muse, mutect2, varscan2
- OR1S2 | c.48A>C p.Q16H | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.838); catalogued as rs975870520, COSV100224217, COSV56919919; called by muse, mutect2, varscan2
- OR2T1 | c.301T>C p.F101L | Missense Mutation (SNP) | VAF 45/152 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.844); catalogued as COSV100822310, COSV63542604; called by muse, mutect2, varscan2
- OR2T27 | c.59A>G p.N20S | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV100788258; called by mutect2, varscan2
- OR52E4 | c.515G>T p.G172V | Missense Mutation (SNP) | VAF 39/101 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV57626149; called by muse, mutect2, varscan2
- OR5D18 | c.142G>T p.V48L | Missense Mutation (SNP) | VAF 28/126 reads (22%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as COSV100450709; called by muse, mutect2, varscan2
- OR6K3 | c.3G>C p.M1? | Translation Start Site (SNP) | VAF 17/54 reads (31%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as COSV100933857, COSV63745286; called by muse, mutect2, varscan2
- OR8U1 | c.759del p.T254Pfs*27 | Frame Shift Del (DEL) | VAF 33/117 reads (28%) | catalogued as COSV100164087; called by pindel, varscan2
- OSR2 | c.169G>T p.G57W | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV99882615; called by muse, mutect2, varscan2
- P4HA1 | c.574A>T p.R192W | Missense Mutation (SNP) | VAF 42/144 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.287); catalogued as COSV99696918; called by muse, mutect2, varscan2
- PASD1 | c.213G>C p.E71D | Missense Mutation (SNP) | VAF 32/129 reads (25%) | SIFT tolerated (0.53); PolyPhen benign (0.013); catalogued as COSV100949387; called by muse, mutect2, varscan2
- PCLO | c.4828C>T p.R1610* | Nonsense Mutation (SNP) | VAF 36/270 reads (13%) | catalogued as COSV61627815, COSV61634849; called by muse, mutect2, varscan2
- PDGFRB | c.3134C>A p.A1045D | Missense Mutation (SNP) | VAF 24/48 reads (50%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.879); catalogued as COSV99641957; called by muse, mutect2, varscan2
- PDHA2 | c.368A>G p.Y123C | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as COSV99756910; called by muse, mutect2, varscan2
- PEX1 | c.481A>G p.I161V | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV99952126; called by muse, mutect2, varscan2
- PHKA2 | c.3610G>T p.A1204S | Missense Mutation (SNP) | VAF 71/249 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs748453047, COSV101177084, COSV66053923; called by muse, mutect2, varscan2
- PIR | c.113C>A p.P38Q | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100712700; called by muse, mutect2, varscan2
- PITPNM2 | c.763C>G p.R255G | Missense Mutation (SNP) | VAF 40/163 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.235); catalogued as COSV54908611, COSV99759016; called by muse, mutect2, varscan2
- PNMA2 | c.511A>C p.S171R | Missense Mutation (SNP) | VAF 17/98 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.119); catalogued as COSV101580628; called by muse, mutect2, varscan2
- POLM | c.500C>T p.A167V | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.999); catalogued as COSV99641806; called by muse, mutect2, varscan2
- PRCP | c.412G>A p.D138N | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.025); catalogued as COSV100475998; called by muse, mutect2, varscan2
- PRKAA2 | c.1227G>C p.Q409H | Missense Mutation (SNP) | VAF 44/80 reads (55%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV100982838; called by muse, mutect2, varscan2
- PRKN | c.292G>T p.E98* | Nonsense Mutation (SNP) | VAF 20/72 reads (28%) | catalogued as COSV100629251; called by muse, varscan2
- PRKN | c.240G>T p.M80I | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs1378447280, COSV100629254; called by muse, varscan2
- PRR23B | c.452A>T p.Q151L | Missense Mutation (SNP) | VAF 21/140 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.171); catalogued as COSV100272084; called by muse, mutect2, varscan2
- PRTG | c.2737G>T p.A913S | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT tolerated (0.55); PolyPhen benign (0.036); catalogued as COSV101221389; called by muse, mutect2
- PTPRM | c.3845C>T p.S1282F | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100157498; called by muse, mutect2, varscan2
- RC3H1 | c.3352G>T p.D1118Y | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.936); catalogued as COSV99281390; called by muse, mutect2, varscan2
- RFX6 | c.2264C>T p.S755F | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.897); catalogued as COSV100263756; called by muse, mutect2, varscan2
- RGS7 | c.782A>T p.Q261L | Missense Mutation (SNP) | VAF 35/137 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.477); catalogued as COSV100467715, COSV100470519; called by muse, mutect2, varscan2
- RGS7 | c.324C>A p.Y108* | Nonsense Mutation (SNP) | VAF 15/78 reads (19%) | catalogued as COSV100467718; called by muse, mutect2, varscan2
- RNF213 | c.15238C>G p.Q5080E | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.452); catalogued as COSV100300641; called by muse, mutect2, varscan2
- S1PR1 | c.995C>A p.P332Q | Missense Mutation (SNP) | VAF 74/176 reads (42%) | SIFT tolerated (0.33); PolyPhen benign (0.206); catalogued as rs7549921, COSV100541566, COSV59514589; called by muse, mutect2, varscan2
- SAAL1 | c.428A>T p.H143L | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV100253887; called by muse, mutect2
- SCN7A | c.856C>G p.P286A | Missense Mutation (SNP) | VAF 73/116 reads (63%) | SIFT tolerated (0.62); PolyPhen benign (0.138); catalogued as COSV101313241, COSV69269643; called by muse, mutect2, varscan2
- SELP | c.1528T>C p.C510R | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV99740044; called by muse, mutect2, varscan2
- SELP | c.169C>G p.R57G | Missense Mutation (SNP) | VAF 50/162 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55248004, COSV99740052; called by muse, mutect2, varscan2
- SEM1 | c.250A>T p.S84C | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.062); catalogued as COSV101303911; called by muse, mutect2, varscan2
- SEMA5A | c.1477C>T p.R493C | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as rs149803731; called by muse, mutect2, varscan2
- SEMA5B | c.799G>A p.G267S | Missense Mutation (SNP) | VAF 57/109 reads (52%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV52108567; called by muse, mutect2, varscan2
- SERPINA4 | c.286C>A p.H96N | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV100097206; called by muse, mutect2, varscan2
- SH3BGRL | c.97G>T p.G33* | Nonsense Mutation (SNP) | VAF 13/57 reads (23%) | catalogued as COSV100943387; called by muse, mutect2, varscan2
- SH3RF1 | c.2662A>G p.I888V | Missense Mutation (SNP) | VAF 34/87 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs1283964220, COSV99499075; called by muse, mutect2, varscan2
- SHOC2 | c.350C>G p.S117* | Nonsense Mutation (SNP) | VAF 28/78 reads (36%) | catalogued as COSV99510044, COSV99510191; called by muse, mutect2, varscan2
- SLC17A8 | c.1080C>A p.H360Q | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV100035565; called by muse, mutect2, varscan2
- SLC22A1 | c.238G>T p.A80S | Missense Mutation (SNP) | VAF 26/113 reads (23%) | SIFT tolerated (0.99); PolyPhen benign (0.012); catalogued as COSV100266738, COSV61452511; called by muse, mutect2, varscan2
- SLC5A5 | c.653A>T p.Q218L | Missense Mutation (SNP) | VAF 29/155 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV99715082; called by muse, mutect2, varscan2
- SMS | c.384C>A p.D128E | Missense Mutation (SNP) | VAF 29/98 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV101048069; called by muse, mutect2, varscan2
- SPACA7 | c.523+2T>A p.X175_splice | Splice Site (SNP) | VAF 13/34 reads (38%) | catalogued as COSV99366547; called by muse, mutect2
- SPOCK3 | c.1300G>A p.V434I | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV100693056; called by muse, mutect2, varscan2
- SPRED1 | c.718C>T p.Q240* | Nonsense Mutation (SNP) | VAF 4/28 reads (14%) | catalogued as COSV100136172, COSV104406855; called by muse, mutect2
- SPTA1 | c.2978C>A p.P993H | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as COSV63750964, COSV63757529; called by muse, mutect2, varscan2
- STK26 | c.1122G>C p.R374S | Missense Mutation (SNP) | VAF 46/121 reads (38%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.003); catalogued as COSV100049030; called by muse, mutect2, varscan2
- SYNE1 | c.12484G>A p.E4162K (on ENST00000367255 / NM_182961.4; = p.E4091K on NM_033071.3) | Missense Mutation (SNP) | VAF 24/142 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99565272; called by muse, mutect2, varscan2
- SYNE2 | c.16397T>A p.M5466K | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as COSV100647738; called by muse, mutect2, varscan2
- TACR3 | c.565G>A p.D189N | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.309); catalogued as COSV100510474, COSV100510863; called by muse, mutect2, varscan2
- TAF3 | c.664C>T p.Q222* | Nonsense Mutation (SNP) | VAF 29/83 reads (35%) | catalogued as COSV100720156; called by muse, mutect2, varscan2
- TBX22 | c.968C>T p.S323F | Missense Mutation (SNP) | VAF 38/107 reads (36%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.956); catalogued as COSV64785585; called by muse, mutect2, varscan2
- TCERG1 | c.1439C>T p.P480L | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.212); catalogued as rs751794499, COSV57034148; called by muse, mutect2, varscan2
- TENT5D | c.431G>T p.W144L | Missense Mutation (SNP) | VAF 52/164 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100382757; called by muse, mutect2, varscan2
- TFDP3 | c.740T>A p.L247Q | Missense Mutation (SNP) | VAF 43/190 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV100033394; called by muse, mutect2, varscan2
- THEG | c.732C>G p.F244L | Missense Mutation (SNP) | VAF 55/257 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV100700616; called by muse, mutect2, varscan2
- THOC2 | c.33G>T p.E11D | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT tolerated (0.54); PolyPhen benign (0.026); catalogued as COSV99833398; called by muse, mutect2, varscan2
- THSD7A | c.436T>A p.C146S | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101448721; called by muse, mutect2, varscan2
- TLR4 | c.345G>T p.Q115H (on ENST00000355622 / NM_138554.5; = p.Q75H on NM_003266.4) | Missense Mutation (SNP) | VAF 42/78 reads (54%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.888); catalogued as COSV100790649; called by muse, mutect2, varscan2
- TMTC2 | c.1226C>G p.T409R | Missense Mutation (SNP) | VAF 10/152 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); catalogued as rs754452313, COSV58263248; called by muse, mutect2
- TOGARAM2 | c.2027A>G p.K676R | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.945); catalogued as rs1232384763, COSV101091135; called by muse, mutect2, varscan2
- TP53 | c.192dup p.R65Qfs*84 | Frame Shift Ins (INS) | VAF 128/269 reads (48%) | catalogued as COSV53031922; called by mutect2, pindel, varscan2
- TRMT1 | c.931G>T p.V311L | Missense Mutation (SNP) | VAF 22/42 reads (52%) | SIFT tolerated (0.12); PolyPhen benign (0.188); catalogued as rs1208523013, COSV99679090; called by muse, mutect2, varscan2
- TRPM6 | c.2323C>T p.Q775* | Nonsense Mutation (SNP) | VAF 26/159 reads (16%) | catalogued as COSV100666352, COSV100666379; called by muse, mutect2, varscan2
- TSPAN8 | c.646C>A p.L216M | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.34); catalogued as COSV56077399, COSV56080076; called by muse, mutect2
- TSPYL2 | c.1022del p.P341Qfs*56 | Frame Shift Del (DEL) | VAF 44/138 reads (32%) | catalogued as COSV60236754; called by mutect2, pindel, varscan2
- TTN | c.41792C>A p.T13931K (on ENST00000591111; = p.T6507K on NM_003319.4) | Missense Mutation (SNP) | VAF 28/42 reads (67%) | PolyPhen possibly damaging (0.813); catalogued as rs1398854469, COSV100614351; called by muse, mutect2, varscan2
- TTN | c.39397A>T p.T13133S (on ENST00000591111; = p.T5709S on NM_003319.4) | Missense Mutation (SNP) | VAF 51/80 reads (64%) | PolyPhen probably damaging (0.994); catalogued as COSV100614356; called by muse, mutect2, varscan2
- TUBE1 | c.769G>C p.A257P | Missense Mutation (SNP) | VAF 62/155 reads (40%) | SIFT tolerated (0.18); PolyPhen benign (0.048); catalogued as COSV100898287; called by muse, mutect2, varscan2
- UBN2 | c.1279G>C p.E427Q | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); catalogued as COSV56035115, COSV99943985; called by muse, mutect2, varscan2
- UNC5D | c.1171G>T p.V391L | Missense Mutation (SNP) | VAF 63/223 reads (28%) | SIFT tolerated (0.21); PolyPhen benign (0.055); catalogued as COSV99775459; called by muse, mutect2, varscan2
- USP29 | c.1658G>T p.S553I | Missense Mutation (SNP) | VAF 42/234 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.877); catalogued as COSV54141807, COSV54147240; called by muse, mutect2, varscan2
- UTP14A | c.538G>T p.A180S | Missense Mutation (SNP) | VAF 31/114 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.596); catalogued as COSV100928962; called by muse, mutect2, varscan2
- VNN1 | c.421del p.D141Tfs*57 | Frame Shift Del (DEL) | VAF 30/108 reads (28%) | catalogued as COSV63389763; called by mutect2, pindel, varscan2
- WEE1 | c.1078G>T p.V360F | Missense Mutation (SNP) | VAF 36/101 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100219761; called by muse, varscan2
- XPNPEP2 | c.1682A>T p.D561V | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV64369587; called by muse, mutect2, varscan2
- ZAN | c.1067T>A p.V356E | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100769749; called by muse, mutect2, varscan2
- ZNF33A | c.2033G>A p.G678E (on ENST00000458705 / NM_006974.3; = p.G679E on NM_006954.2) | Missense Mutation (SNP) | VAF 21/119 reads (18%) | SIFT tolerated (1); PolyPhen probably damaging (0.955); catalogued as COSV100275834; called by muse, mutect2, varscan2
- ZNF532 | c.3643C>G p.H1215D | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.849); catalogued as COSV100266617; called by muse, mutect2, varscan2
- ZNF536 | c.220G>T p.G74C | Missense Mutation (SNP) | VAF 34/83 reads (41%) | SIFT tolerated, low confidence (0.15); PolyPhen possibly damaging (0.906); catalogued as COSV100835265; called by muse, mutect2, varscan2
- ZNF626 | c.647T>A p.L216H | Missense Mutation (SNP) | VAF 36/74 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV101656986; called by muse, mutect2, varscan2
- ZNF667 | c.760C>T p.Q254* | Nonsense Mutation (SNP) | VAF 30/171 reads (18%) | catalogued as COSV99410478; called by muse, mutect2
- ANK2 | c.8830dup p.T2944Nfs*15 | Frame Shift Ins (INS) | VAF 61/173 reads (35%) | called by mutect2, pindel, varscan2
- FBXO42 | c.860C>A p.S287Y | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, mutect2
- HPSE2 | c.827del p.G276Afs*11 | Frame Shift Del (DEL) | VAF 22/58 reads (38%) | called by mutect2, pindel, varscan2
- IGHV2-26 | c.68del p.L23* | Frame Shift Del (DEL) | VAF 11/47 reads (23%) | called by mutect2, pindel, varscan2
- LHX1 | c.397+1G>C p.X133_splice | Splice Site (SNP) | VAF 7/31 reads (23%) | called by muse, mutect2, varscan2
- MFSD9 | c.847dup p.S283Ffs*23 | Frame Shift Ins (INS) | VAF 15/84 reads (18%) | called by mutect2, pindel, varscan2
- MRC1 | c.1069G>T p.D357Y | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.736); called by muse, varscan2
- OR11H1 | c.457T>A p.W153R | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- OR2M2 | c.467del p.G156Efs*6 | Frame Shift Del (DEL) | VAF 55/332 reads (17%) | called by pindel, varscan2
- SLC2A13 | c.1355del p.G452Vfs*6 | Frame Shift Del (DEL) | VAF 10/59 reads (17%) | called by mutect2, pindel, varscan2
- ZNF808 | c.601del p.Q201Kfs*13 | Frame Shift Del (DEL) | VAF 89/247 reads (36%) | called by mutect2, pindel, varscan2
- ADRA1A | c.531G>A p.Q177= | Silent (SNP) | VAF 8/39 reads (21%) | catalogued as COSV99371071; called by muse, mutect2, varscan2
- ANKRD27 | c.1902C>T p.S634= | Silent (SNP) | VAF 20/77 reads (26%) | catalogued as COSV100042837; called by muse, mutect2, varscan2
- AQR | c.789G>A p.L263= | Silent (SNP) | VAF 22/56 reads (39%) | catalogued as COSV99333974; called by muse, mutect2, varscan2
- C8B | c.1545C>T p.V515= | Silent (SNP) | VAF 20/55 reads (36%) | catalogued as COSV100980777; called by muse, mutect2, varscan2
- CARD6 | c.2292G>A p.K764= | Silent (SNP) | VAF 64/196 reads (33%) | catalogued as COSV99620828; called by muse, mutect2, varscan2
- CHD6 | c.3921C>T p.C1307= | Silent (SNP) | VAF 21/68 reads (31%) | catalogued as COSV100498304; called by muse, mutect2, varscan2
- COL4A5 | c.195A>C p.P65= | Silent (SNP) | VAF 24/127 reads (19%) | catalogued as COSV100087863; called by muse, mutect2, varscan2
- DLG3 | c.1431A>T p.I477= (on ENST00000374360 / NM_021120.4; = p.I140= on NM_020730.3) | Silent (SNP) | VAF 40/161 reads (25%) | catalogued as COSV99529566; called by muse, mutect2, varscan2
- DNAH5 | c.5146C>A p.R1716= | Silent (SNP) | VAF 19/71 reads (27%) | catalogued as CM091941, COSV99450142; called by muse, mutect2, varscan2
- DOCK9 | c.5967T>C p.A1989= (on ENST00000376460 / NM_001366676.2; = p.A1990= on NM_015296.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 7/15 reads (47%) | catalogued as COSV100239397; called by muse, mutect2, varscan2
- ELOVL7 | c.90C>T p.L30= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as COSV70917680; called by muse, mutect2
- EPHA5 | c.2202T>C p.P734= | Silent (SNP) | VAF 40/88 reads (45%) | catalogued as COSV99899082; called by muse, mutect2, varscan2
- FAM120AOS | c.696C>T p.S232= | Silent (SNP) | VAF 14/125 reads (11%) | catalogued as COSV99465539; called by muse, mutect2
- HR | c.3537G>A p.K1179= | Silent (SNP) | VAF 7/44 reads (16%) | catalogued as rs779312247, COSV57193300; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KCNA5 | c.1485C>T p.I495= | Silent (SNP) | VAF 25/114 reads (22%) | catalogued as rs764615241, COSV52906566, COSV52907574; called by muse, mutect2, varscan2
- KCNB2 | c.1338C>T p.N446= | Silent (SNP) | VAF 39/128 reads (30%) | catalogued as rs141965461, COSV73049115; called by muse, mutect2, varscan2
- KIAA1210 | c.3421C>A p.R1141= | Silent (SNP) | VAF 20/106 reads (19%) | catalogued as rs745577960, COSV101274165, COSV101274303, COSV68176979; called by muse, mutect2, varscan2
- KIF17 | c.2877C>T p.S959= | Silent (SNP) | VAF 34/80 reads (43%) | catalogued as COSV99929071; called by muse, mutect2, varscan2
- KRT1 | c.645G>A p.L215= | Silent (SNP) | VAF 29/83 reads (35%) | catalogued as COSV99358792; called by muse, mutect2, varscan2
- KRT18 | c.393G>A p.K131= | Silent (SNP) | VAF 13/44 reads (30%) | catalogued as COSV101184025; called by muse, mutect2, varscan2
- KSR1 | c.1941G>T p.V647= (on ENST00000644974 / NM_001367810.1; = p.V532= on NM_014238.2) | Silent (SNP) | VAF 5/16 reads (31%) | catalogued as COSV99259655; called by muse, mutect2, varscan2
- LAMB1 | c.261G>A p.E87= | Silent (SNP) | VAF 36/120 reads (30%) | catalogued as COSV99740861; called by muse, mutect2, varscan2
- LCE1A | c.147A>G p.G49= | Silent (SNP) | VAF 25/83 reads (30%) | catalogued as COSV100632071; called by muse, mutect2, varscan2
- LHX8 | c.828T>C p.C276= | Silent (SNP) | VAF 51/99 reads (52%) | catalogued as rs765140176, COSV99633792; called by muse, mutect2, varscan2
- MAGI2 | c.150C>A p.G50= | Silent (SNP) | VAF 34/118 reads (29%) | catalogued as COSV100834578; called by muse, mutect2, varscan2
- MGMT | c.690G>A p.S230= (on ENST00000306010; = p.S199= on NM_002412.5) | Silent (SNP) | VAF 18/36 reads (50%) | catalogued as rs764371384, COSV100023208, COSV60026748; called by muse, mutect2, varscan2
- MYLK | c.1359C>A p.P453= | Silent (SNP) | VAF 28/58 reads (48%) | catalogued as COSV100659127; called by muse, varscan2
- NAP1L3 | c.291G>A p.V97= | Silent (SNP) | VAF 13/46 reads (28%) | catalogued as COSV100220405; called by muse, mutect2, varscan2
- NLRP12 | c.24C>T p.D8= | Silent (SNP) | VAF 15/84 reads (18%) | catalogued as rs577507616, COSV60745112, COSV60748820; called by muse, mutect2, varscan2
- NPBWR2 | c.936C>T p.N312= | Silent (SNP) | VAF 22/65 reads (34%) | catalogued as COSV100871114, COSV63899779; called by muse, mutect2, varscan2
- OR5K4 | c.348G>T p.A116= | Silent (SNP) | VAF 190/341 reads (56%) | catalogued as COSV100721351, COSV61583344; called by muse, mutect2, varscan2
- OR6C3 | c.678G>T p.P226= | Silent (SNP) | VAF 43/117 reads (37%) | catalogued as rs371374392, COSV101110303; called by muse, mutect2, varscan2
- OR6X1 | c.99C>T p.Y33= | Silent (SNP) | VAF 13/112 reads (12%) | catalogued as rs748847304, COSV100020541; called by muse, mutect2, varscan2
- PCDHB7 | c.1989G>T p.V663= | Silent (SNP) | VAF 17/75 reads (23%) | catalogued as COSV99176978; called by muse, mutect2, varscan2
- PCDHGA2 | c.486A>T p.V162= | Silent (SNP) | VAF 31/66 reads (47%) | catalogued as COSV53993673, COSV99538880; called by muse, mutect2, varscan2
- PLCE1 | c.738T>C p.N246= | Silent (SNP) | VAF 22/47 reads (47%) | catalogued as COSV99595080; called by muse, mutect2, varscan2
- PRAMEF15 | c.309A>G p.Q103= | Silent (SNP) | VAF 73/184 reads (40%) | called by muse, mutect2, varscan2
- PRAMEF4 | c.984G>A p.L328= | Silent (SNP) | VAF 58/138 reads (42%) | catalogued as COSV99339849; called by mutect2, varscan2
- PRDM9 | c.255G>T p.V85= | Silent (SNP) | VAF 17/60 reads (28%) | catalogued as COSV99690500; called by muse, mutect2, varscan2
- RBP3 | c.2976C>A p.L992= | Silent (SNP) | VAF 33/131 reads (25%) | called by muse, mutect2, varscan2
- RERGL | c.507C>T p.I169= | Silent (SNP) | VAF 21/86 reads (24%) | catalogued as rs769360835, COSV99967828, COSV99967934; called by muse, mutect2, varscan2
- RIF1 | c.5286A>G p.T1762= | Silent (SNP) | VAF 20/79 reads (25%) | catalogued as COSV99690609; called by muse, mutect2, varscan2
- SAMD7 | c.177T>C p.N59= | Silent (SNP) | VAF 30/160 reads (19%) | catalogued as COSV100156942; called by muse, varscan2
- SASH1 | c.3714C>T p.F1238= | Silent (SNP) | VAF 30/121 reads (25%) | catalogued as COSV100821217; called by muse, mutect2, varscan2
- SGK2 | c.246G>A p.L82= | Silent (SNP) | VAF 10/32 reads (31%) | catalogued as COSV100414667; called by muse, mutect2, varscan2
- SHH | c.606G>A p.S202= | Silent (SNP) | VAF 6/27 reads (22%) | catalogued as COSV99793423; called by muse, mutect2, varscan2
- SLC17A9 | c.570C>T p.S190= | Silent (SNP) | VAF 50/153 reads (33%) | catalogued as rs774383637, COSV64847243; called by muse, mutect2, varscan2
- SLC18A3 | c.1305G>A p.G435= | Silent (SNP) | VAF 15/38 reads (39%) | catalogued as COSV100340192; called by muse, mutect2, varscan2
- SLC22A11 | c.738C>T p.G246= | Silent (SNP) | VAF 19/132 reads (14%) | catalogued as rs764766339, COSV57252860; called by muse, mutect2, varscan2
- SLC44A5 | c.264C>T p.N88= | Silent (SNP) | VAF 14/41 reads (34%) | catalogued as COSV100902057; called by muse, mutect2, varscan2
- SLCO1B1 | c.936C>A p.T312= | Silent (SNP) | VAF 17/57 reads (30%) | catalogued as COSV99918544; called by muse, mutect2, varscan2
- SNTG1 | c.1035C>A p.L345= | Silent (SNP) | VAF 10/57 reads (18%) | catalogued as COSV52474775, COSV99383845; called by muse, mutect2, varscan2
- SV2B | c.2025A>G p.P675= | Silent (SNP) | VAF 9/77 reads (12%) | catalogued as COSV100370697; called by muse, mutect2, varscan2
- TCAF2 | c.963C>T p.C321= | Silent (SNP) | VAF 18/98 reads (18%) | catalogued as rs1374020473, COSV100633627; called by muse, mutect2, varscan2
- TGM5 | c.327G>C p.T109= | Silent (SNP) | VAF 12/132 reads (9%) | catalogued as COSV55012285, COSV99589000; called by muse, mutect2
- THSD7B | c.1185G>A p.L395= | Silent (SNP) | VAF 29/47 reads (62%) | catalogued as COSV99751451; called by muse, mutect2, varscan2
- TLR4 | c.186C>T p.S62= (on ENST00000355622 / NM_138554.5; = p.S22= on NM_003266.4) | Silent (SNP) | VAF 18/151 reads (12%) | catalogued as COSV100790648; called by muse, mutect2, varscan2
- TMEM116 | c.267C>T p.I89= | Silent (SNP) | VAF 21/83 reads (25%) | catalogued as rs143338734; called by muse, mutect2, varscan2
- TPO | c.378C>A p.I126= | Silent (SNP) | VAF 32/99 reads (32%) | catalogued as COSV100221120; called by muse, mutect2, varscan2
- TTN | c.44418G>A p.Q14806= (on ENST00000591111; = p.Q7382= on NM_003319.4) | Silent (SNP) | VAF 24/35 reads (69%) | catalogued as COSV100614346; called by muse, mutect2, varscan2
- TTN | c.42447C>A p.I14149= (on ENST00000591111; = p.I6725= on NM_003319.4) | Silent (SNP) | VAF 27/104 reads (26%) | catalogued as COSV100614347; called by muse, mutect2, varscan2
- UBN2 | c.1113C>T p.D371= | Silent (SNP) | VAF 29/101 reads (29%) | catalogued as COSV99943983; called by muse, mutect2, varscan2
- XKR3 | c.411C>T p.S137= | Silent (SNP) | VAF 36/152 reads (24%) | catalogued as COSV100509273; called by muse, mutect2, varscan2
- ZBTB24 | c.564G>C p.V188= | Silent (SNP) | VAF 69/269 reads (26%) | catalogued as rs1363860544, COSV100018456; called by muse, mutect2, varscan2
- ZNF235 | c.1887T>C p.C629= | Silent (SNP) | VAF 59/120 reads (49%) | catalogued as COSV99349477; called by muse, mutect2, varscan2
- ZNF383 | c.354A>T p.G118= | Silent (SNP) | VAF 42/105 reads (40%) | catalogued as COSV100776758; called by muse, mutect2, varscan2
- ERBB4 | c.1872-134G>T | Intron (SNP) | VAF 17/30 reads (57%) | catalogued as COSV99624136; called by muse, mutect2, varscan2
- GABRA3 | c.-26-27637G>T | Intron (SNP) | VAF 8/36 reads (22%) | catalogued as rs1569415789, COSV100942743; called by muse, mutect2, varscan2
- GP6 | c.*72G>A | 3'UTR (SNP) | VAF 15/48 reads (31%) | catalogued as COSV100117529; called by muse, mutect2, varscan2
- HERC2P3 | n.2322G>A | RNA (SNP) | VAF 10/42 reads (24%) | called by muse, mutect2, varscan2
- HOXC10 | chr12:53991827 C>G | 3'Flank (SNP) | VAF 7/29 reads (24%) | catalogued as COSV100329081; called by muse, mutect2, varscan2
- MIR527 | n.23del | RNA (DEL) | VAF 49/272 reads (18%) | called by mutect2, pindel, varscan2
- SLC26A7 | c.1935+222T>C | Intron (SNP) | VAF 24/64 reads (38%) | catalogued as COSV99403424; called by muse, mutect2, varscan2
- TNK2 | c.1452-73G>T | Intron (SNP) | VAF 22/33 reads (67%) | catalogued as COSV100361373; called by muse, mutect2, varscan2
